Gene-level copy-number profile of tumor specimen ALCH-B27Q-TTP1-A from ALCHEMIST case ALCH-B27Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.4 years (20,956 days).
Specimen ALCH-B27Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 797a73af-6de9-4415-bf90-168b32367618.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B27Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/fa3ef61a-89a7-47b5-9a1c-39b15a9f7f4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 588; copy number 1: 26,695; copy number 2: 28,635; copy number 3: 1,527; copy number 4: 1,144; copy number 5: 176; copy number 6: 87; copy number 9: 2; copy number 11: 3; copy number 12: 3; copy number 13: 5; copy number 14: 1; copy number 17: 1; copy number 32: 6; copy number 34: 9; copy number 35: 9; copy number 49: 4; copy number 68: 6.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr2:218,255,319–218,270,178, 3 genes: AC021016.1, GPBAR1, AAMP.
- chr5:139,684,645–139,747,406, 3 genes: AC008667.1, RNU6-236P, PSD2-AS1.
- chr7:149,838,375–149,867,479, 3 genes: ZNF862, AC004877.2, AC004877.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes (within-gene range 0–1): ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:133,414,358–133,479,127, 3 genes (within-gene range 0–1): ADAMTS13, CACFD1, SLC2A6.
- chr10:42,209,990–42,210,383, 1 gene: AL031601.1.
- chr10:87,357,720–88,584,530, 22 genes (within-gene range 0–1): NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr11:76,210,956–76,216,025, 1 gene: LINC02761.
- chr12:132,565,071–132,566,425, 1 gene (within-gene range 0–1): AC131212.2.
- chr15:25,041,974–25,054,304, 3 genes (within-gene range 0–1): SNORD109A, SNORD116-1, SNORD116-2.
- chr16:3,018,445–3,036,944, 4 genes (within-gene range 0–1): TNFRSF12A, HCFC1R1, THOC6, BICDL2.
- chr16:70,661,204–70,686,053, 2 genes: MTSS2, AC020763.4.
- chr16:70,713,987–70,716,890, 1 gene (within-gene range 0–1): AC020763.3.
- chr17:81,952,507–82,017,406, 3 genes: NOTUM, AC145207.7, ASPSCR1.
- chr17:82,078,338–82,098,294, 1 gene: FASN.
- chr19:58,367,618–58,381,030, 1 gene: ZNF837.
- chr20:63,939,829–63,956,985, 4 genes (within-gene range 0–1): UCKL1, MIR1914, MIR647, UCKL1-AS1.
- chr21:43,465,309–43,467,298, 1 gene (within-gene range 0–3): AP001048.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 312 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–197,341, 3 genes, copy number 5 (within-gene range 1–5): LINC01986, AC066595.1, CHL1-AS2.
- chr3:165,122,713–165,197,109, 3 genes, copy number 5: Y_RNA, LINC02023, SLITRK3.
- chr5:58,198–10,777,062, 231 genes, copy number 5–6 (broad region; genes not listed).
- chr8:127,079,874–127,482,139, 3 genes, copy number 12–13 (within-gene range 2–13): PRNCR1, AC020688.1, CASC8.
- chr8:127,322,183–127,636,867, 3 genes, copy number 12–13: POU5F1B, CCAT2, AC104370.1.
- chr8:132,507,962–132,565,246, 1 gene, copy number 13: HPYR1.
- chr8:132,685,007–132,760,712, 2 genes, copy number 6: TMEM71, AF228727.1.
- chr8:133,191,039–133,231,690, 1 gene, copy number 5: CCN4.
- chr8:133,325,997–133,409,107, 3 genes, copy number 9–11: KC877373.1, AF186190.1, ST13P6.
- chr8:133,644,598–133,668,701, 2 genes, copy number 11: AC090821.1, Metazoa_SRP.
- chr8:134,722,947–134,723,949, 1 gene, copy number 14: AC087045.2.
- chr11:1,947,278–1,984,522, 1 gene, copy number 13 (within-gene range 3–13): MRPL23.
- chr19:27,793,431–27,984,984, 10 genes, copy number 5 (within-gene range 3–5): AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1.
- chr20:30,484,925–31,870,747, 39 genes, copy number 6–68 (within-gene range 4–68): 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15.
- chr21:43,446,601–43,453,902, 1 gene, copy number 5: LINC00319.
- chr21:44,107,373–44,210,114, 5 genes, copy number 6 (within-gene range 1–6): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.
- chr22:16,725,072–16,821,699, 3 genes, copy number 5: AC005301.2, LINC01665, XKR3.

Autosomal genes at a single copy (total copy number 1): 24,366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
